Surgical pathology report (de-identified scan), TCGA case TCGA-O2-A52V, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CALGB, specimen TCGA-O2-A52V-01A (Primary Tumor).

[page 1 of 3]
Patient:

Surg Path

CLINICAL HISTORY:
Lung cancer.

GROSS EXAMINATION:

A. "Bronchial margin (AF1)", received fresh for frozen section consultation, is a 94.6 gram, 14 x 7 x 5.5 cm lobectomy specimen. The pleura is purple-tan and smooth with a minimal amount of anthracotic pigment and multiple radiating staple lines from the hilum. In addition, there is a 4.5 x 3 cm roughened area embedded with innumerable staples located 1 cm from the bronchial margin. The specimen is serially sectioned to demonstrate a crepitant tan parenchymal cut surface with no masses or lesions noted. A bronchial margin has been frozen as AF1, and the remnant is submitted in A1. Additional representative sections are submitted as follows:

- A2- vascular margins
- A3-4 lymph nodes
- A5- uninvolved peripheral parenchyma
- A6- uninvolved central parenchyma

B. "Level 11 lymph node", received in formalin is two fragments of gray-black tissue measuring from 1 x 0.5 x 0.4 cm to 1.4 x 1 x 0.6 cm. The fragments are submitted in their entirety in block B1.

C. "Level 10 lymph node", received in formalin is a gray-black fragment of soft tissue measuring 1.5 x 1 x 0.6 cm. The fragment is submitted in its entirety in C1.

D. "Left upper lobe wedge and chest wall", received in formalin is a 374 gram, 20 x 10 x 6 cm wedge of lung with an attached 11.5 x 10.1 cm segment of chest wall. The pleura is purple-tan with focal fibrinous adhesions and contains multiple adherent staple lines. In addition, there is a 5.5 x 2.5 cm roughened area which is embedded with multiple staples which will be inked blue. The chest wall is composed of three fragments of rib and adherent soft tissue. The exposed soft tissue is inked black. The staple lines are removed and the underlying parenchyma is inked red. The lung wedge is serially sectioned to demonstrate a friable 7.5 x 7 x 5.5 cm necrotic mass. The mass is located 1 cm from the aforementioned blue margin, and involves the chest wall.

BLOCK SUMMARY:

- D1- tumor with respect to the blue inked parenchymal margin
- D2-3 sections of tumor with intact pleura
- D4-5 tumor with adjacent uninvolved parenchyma
- D6- medial margin of inferior rib (sent for decal)
- D7- lateral margin of inferior rib (sent for decal)
- D8- medial margin of middle rib (sent for decal)
- D9- lateral margin of middle rib (sent for decal)
- D10- medial margin of superior rib (sent for decal)
- D11- lateral margin of superior rib (sent for decal)
- D12- anterior soft tissue margin of ribs, tangentially cut
- D13- tumor in relation to superior rib (sent for decal)

Please note that D6-11 and D13 are sent for decal.

E. "Final chest wall margin", received in formalin are multiple tan-gray fragments of soft tissue and bone measuring 3.5 x 2.5 x 1.5 cm in aggregate. The fragments are sectioned and submitted entirely in blocks E1-3 (E4-3 in

1CD-0.3

carcinoma, squamous cell, NOS 8070/3
Site: LVNG, Upper lobe C34.1

lw
11/12/12

[page 2 of 3]
decal).

F. "Level 9 lymph node", received in formalin is a 1.5 x 0.5 x 0.5 cm tan-black fragment of soft tissue. The fragment is submitted in its entirety as F1.

INTRA OPERATIVE CONSULTATION:

A. "Bronchial margin": AFI-negative for tumor

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: EN BLOC EXCISION OF LUNG AND CHEST WALL, COMPLETION LOBECTOMY AND MEDIASTINAL LYMPH NODE BIOPSIES

PATHOLOGIC STAGE (AJCC 6th Edition): pT3 pN0 pM0

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "BRONCHIAL MARGIN" (COMPLETION LOBECTOMY):

REMAINT OF UPPER LOBE OF LEFT LUNG, NO EVIDENCE OF MALIGNANCY.
BRONCHOVASCULAR MARGINS OF RESECTION ARE FREE OF TUMOR.
THREE HILAR LYMPH NODES, NO EVIDENCE OF MALIGNANCY.
LUNG TISSUE FEATURES CENTRIOLOBULAR EMPHYSEMA WITH CHRONIC BRONCHITIS AND SMALL AIRWAYS DISEASE.

B. "LEVEL 11 LYMPH NODE" (BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

C. "LEVEL 10 LYMPH NODE" (BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

D. "LEFT UPPER LOBE WEDGE CHEST WALL" (EN BLOC EXCISION OF LUNG AND CHEST WALL):

CARCINOMA OF LUNG:

Histologic type:	SQUAMOUS CELL
Histologic grade:	MODERATELY DIFFERENTIATED (G2)

Extent of invasion

- Max. tumor diameter:	7.5 CM
- Mainstem bronchus:	NEGATIVE
- Visceral pleura:	PRESENT
- Chest wall:	PRESENT, NO OSSEOUS INVASION IDENTIFIED
- Mediastinum:	NEGATIVE
- >1 tumor nodules?	NEGATIVE
- Panlobar atelectasis?	NEGATIVE

Margins

[page 3 of 3]
- Bronchial: REPORTED SEPARATELY
- Vascular: REPORTED SEPARATELY
- Parenchymal: LUNG PARENCHYMAL MARGIN NEGATIVE, ADDITIONAL SOFT

- Pleural: TISSUE MARGIN REPORTED SEPARATELY
NEGATIVE

Other prognostic features

- Vascular invasion: NEGATIVE

Regional lymph nodes: NO SPECIMEN NODES, ADDITIONAL N1 NODES REPORTED
ABOVE

Additional findings: EMPHYSEMA, CHRONIC BRONCHITIS, POSTOBSTRUCTIVE
ORGANIZING PNEUMONIA

E. "FINAL CHEST WALL MARGIN" (EXCISION):

FRAGMENTS OF BONE AND SOFT TISSUE CONTAINING NODULAR DEPOSIT OF MODERATELY
DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 2 CM IN GREATEST DIMENSION (SLIDE
MEASUREMENT).

BONY INVASION IS NOT IDENTIFIED.

MARGINS NOT EVALUATED IN VIEW OF FRAGMENTED SPECIMEN.

F. "LEVEL 9 LYMPH NODE" (BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

I certify that I personally conducted the diagnostic evaluation of the above
specimen(s) and have rendered the above diagnosis(es).

Performed by:

Electronically signed:

Patient:

MRN

11/12/12

Source: NCI Genomic Data Commons file 0e6f2970-0829-45a9-97db-63621236c6d8 (TCGA-O2-A52V.0C9E8CD7-55DF-4BFF-AE29-891BD33C2EB4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).